Surgical pathology report (de-identified scan), TCGA case TCGA-VR-AA4G, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-AA4G-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, squamous cell NOS

Site: Esophagus, middle third

QWB/8/14

807013

C15.4

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Esophagus (Mid third)

1 - "Bronchial artery lymph node":

- Material consists of medium caliber arterial wall. Absence of lymphoid tissue in the material examined.

2 - "Lymph node from level 3":

- Fibroadipose congested tissue. Absence of lymphoid tissue in the material.

3 - "Infra-carinal lymph node":

- Absence of metastasis in 4 lymph nodes (0/4).

4 - "Lymph node from level 4, right side":

- Absence of metastasis in 5 lymph nodes (0/5).

5 - "Lymph node from aorto-pulmonary window":

- Fibroadipose congested tissue. Absence of lymphoid tissue in the examined material.

6 - "Esophagogastricectomy":

- Moderately differentiated ulcerated squamous cell carcinoma, measuring 3.3 x 1.5cm, infiltrating the wall up to the muscularis propria, located in the middle third of the esophagus;

- Vascular and perineural invasions not detected;

- Proximal, distal and radial margins free of neoplasia;

- Epidermoid carcinoma "in situ" in the epithelium adjacent to the tumor;

- Stomach free of neoplasia;

- Presence of metastasis in one periesophageal lymph node examined (1/1), with no extracapsular extension;

- Presence of metastasis in 1 of 25 lymph nodes examined from lesser curvature (1/25) without extracapsular extension.

7 - "Recurrent lymph node":

- Presence of metastasis in 1 of 2 examined lymph nodes (1/2), without extracapsular extension.

[page 2 of 2]
- 8- "Esophageal margin":
- Margin free of neoplasia.

PATHOLOGIC STAGING

Topography	Morphology	Stage
Middle third of esophagus	Squamous cell carcinoma, NOS	pT2 pN2

Source: NCI Genomic Data Commons file dc3cdb1c-460b-4794-b040-256760068d53 (TCGA-VR-AA4G.AB01CF40-5081-4549-8E6C-B2B257C591DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).